Somatic mutation profile of tumor specimen 547f521a-5851-426c-a125-d9d82c (aliquot 547f521a-5851-426c-a125-d9d82c_D6_1) from CPTAC case 20BR007, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.9 years (19,679 days).
Specimen 547f521a-5851-426c-a125-d9d82c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d801c01b-c755-4dbb-987f-e1520423457c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 58f39d9c-9c17-4268-a206-564f83 (Blood Derived Normal), aliquot 58f39d9c-9c17-4268-a206-564f83_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85d45920-6a97-4ded-8008-ccafc5c5c885

The open-access MAF lists 123 somatic variants for this specimen: 95 protein-altering or splice-affecting, 16 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 16, In Frame Del 6, Intron 5, Frame Shift Del 4, RNA 3, 3'UTR 2, 5'UTR 1, Splice Site 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC099489.1 | c.4432A>G p.R1478G | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.072); catalogued as rs973348461; called by muse, mutect2, varscan2
- CAMTA1 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs1057524631, COSV57882651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCN3 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.076); catalogued as rs777023733; called by muse, mutect2, varscan2
- CSPG4 | c.5677C>T p.R1893C | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs897200627; called by muse, mutect2, varscan2
- EMILIN1 | c.346A>T p.M116L | Missense Mutation (SNP) | VAF 57/398 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV66695135; called by muse, mutect2, varscan2
- FLG2 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 280/737 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV66167295; called by muse, mutect2, varscan2
- GUCY1A2 | c.372G>T p.R124S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as COSV56488355; called by muse, mutect2, varscan2
- HELZ2 | c.7414G>A p.V2472M (on ENST00000467148 / NM_001037335.2; = p.V1903M on NM_033405.3) | Missense Mutation (SNP) | VAF 32/654 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs748230640, COSV64443501; called by muse, mutect2
- HSPB8 | c.335T>C p.F112S | Missense Mutation (SNP) | VAF 7/199 reads (4%) | catalogued as rs1422296101; called by muse, mutect2
- KIAA1109 | c.12188G>C p.R4063T | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52662741, COSV99175208; called by muse, mutect2, varscan2
- KIF18B | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59272441; called by muse, mutect2, varscan2
- KISS1 | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 110/537 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336218292; called by mutect2, varscan2
- MPP6 | c.1411G>A p.V471M | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs561462920; called by muse, mutect2, varscan2
- MYO1E | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775776382, COSV55686499; called by muse, mutect2, varscan2
- OR9G4 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs754042645, COSV57248241; called by muse, mutect2
- PKD1L3 | c.3068G>T p.C1023F | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV58665725; called by muse, mutect2, varscan2
- POLQ | c.3707A>T p.N1236I | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.202); catalogued as COSV51756944; called by muse, mutect2, varscan2
- POM121L12 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 34/615 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV68692577; called by muse, mutect2
- RFTN1 | c.654C>A p.N218K | Missense Mutation (SNP) | VAF 88/525 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs565887542; called by muse, mutect2, varscan2
- SHANK2 | c.4195G>T p.V1399L | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV53602923; called by muse, mutect2
- SRF | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 177/440 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV54838528; called by muse, mutect2, varscan2
- TMEM117 | c.1454C>G p.S485W | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs146778152; called by muse, mutect2, varscan2
- ACSL4 | c.662G>A p.C221Y (on ENST00000340800 / NM_022977.2; = p.C180Y on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADAMTS6 | c.315T>G p.D105E | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.014); called by muse, mutect2
- AGBL5 | c.1880T>C p.L627S | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- AHNAK2 | c.8039C>A p.A2680D | Missense Mutation (SNP) | VAF 23/334 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- ANKRD11 | c.4819C>G p.Q1607E | Missense Mutation (SNP) | VAF 114/296 reads (39%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARFGEF3 | c.4852A>G p.T1618A | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARHGAP21 | c.3089_3099del p.A1030Dfs*17 | Frame Shift Del (DEL) | VAF 43/191 reads (23%) | called by mutect2, pindel, varscan2
- ARHGAP31 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 50/679 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- ASH1L | c.1363T>A p.S455T | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); called by muse, mutect2
- BIRC6 | c.3115T>G p.S1039A | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CBLN4 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2
- CCDC54 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CCN3 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CCR10 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CDC42BPG | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CEP72 | c.1180T>A p.S394T | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CFAP206 | c.713_715del p.Y238_R239delinsC | In Frame Del (DEL) | VAF 56/282 reads (20%) | called by mutect2, pindel, varscan2
- CLEC11A | c.670A>T p.T224S | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by mutect2, varscan2
- COL19A1 | c.2496G>C p.K832N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- COL4A4 | c.4801T>C p.F1601L | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CRYBG2 | c.4535A>T p.Y1512F | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.185); called by muse, mutect2
- CTAGE6 | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- DDN | c.305_309del p.L102Rfs*135 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- DNAH7 | c.2356G>T p.G786W | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC7 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FAR1 | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- FCRL3 | c.1654del p.A552Pfs*7 | Frame Shift Del (DEL) | VAF 52/274 reads (19%) | called by pindel, varscan2
- FSIP2 | c.4033G>C p.V1345L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- GPAA1 | c.806A>G p.Q269R | Missense Mutation (SNP) | VAF 119/508 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- GPR135 | c.1377G>A p.M459I | Missense Mutation (SNP) | VAF 93/281 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GRIA4 | c.1931C>A p.A644D | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HSD17B10 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 32/880 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IL17RD | c.1310A>T p.H437L | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- JAG1 | c.3142C>G p.L1048V | Missense Mutation (SNP) | VAF 29/646 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- KAT6A | c.5832C>A p.N1944K | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF18B | c.473_493del p.V158_H164del | In Frame Del (DEL) | VAF 24/104 reads (23%) | called by mutect2, pindel, varscan2
- KIF26B | c.5621_5632del p.V1874_G1877del | In Frame Del (DEL) | VAF 60/207 reads (29%) | called by mutect2, pindel, varscan2
- KNG1 | c.485A>C p.H162P | Missense Mutation (SNP) | VAF 36/571 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- KRT6A | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 72/1056 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2
- MAPK8 | c.997-2A>T p.X333_splice | Splice Site (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- MDC1 | c.5660A>C p.N1887T | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2
- MECOM | c.509C>G p.A170G (on ENST00000468789 / NM_001105078.4; = p.A358G on NM_004991.4) | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPPED1 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP12 | c.2729A>T p.H910L | Missense Mutation (SNP) | VAF 175/452 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- NOS2 | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- NUMA1 | c.3108_3115del p.N1036Kfs*58 | Frame Shift Del (DEL) | VAF 89/493 reads (18%) | called by mutect2, pindel, varscan2
- PALD1 | c.470A>G p.E157G | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PCLO | c.4999T>A p.F1667I | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PID1 | c.155A>T p.K52I (on ENST00000354069 / NM_001330156.1; = p.K50I on NM_017933.5) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PJA2 | c.1684G>T p.V562F | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRSS37 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 125/363 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PUM1 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 97/292 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PXDC1 | c.284A>C p.D95A | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- RET | c.2407A>C p.I803L | Missense Mutation (SNP) | VAF 188/790 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- RWDD2B | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SCNN1D | c.814G>A p.A272T (on ENST00000338555; = p.A436T on NM_001130413.4) | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SCNN1D | c.815C>G p.A272G (on ENST00000338555; = p.A436G on NM_001130413.4) | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SND1 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRNP200 | c.3604C>G p.L1202V | Missense Mutation (SNP) | VAF 236/978 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by mutect2, varscan2
- SUGP1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 62/422 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- TDRD6 | c.4574_4588del p.A1525_D1529del | In Frame Del (DEL) | VAF 22/224 reads (10%) | called by mutect2, varscan2
- TLR4 | c.2399G>T p.S800I (on ENST00000355622 / NM_138554.5; = p.S760I on NM_003266.4) | Missense Mutation (SNP) | VAF 34/443 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); called by muse, mutect2
- TNFRSF13B | c.237T>A p.Y79* | Nonsense Mutation (SNP) | VAF 30/461 reads (7%) | called by muse, mutect2
- TP53 | c.652_654del p.V218del | In Frame Del (DEL) | VAF 189/708 reads (27%) | called by pindel, varscan2
- TPH1 | c.1201_1227del p.Y401_Q409del | In Frame Del (DEL) | VAF 51/348 reads (15%) | called by mutect2, pindel, varscan2
- TRPV1 | c.1548C>G p.F516L | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- UNC80 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- WSB1 | c.498G>C p.L166F | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- XPO7 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- XPR1 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZAN | c.6943A>T p.T2315S | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF18 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF827 | c.3049A>G p.K1017E | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ABCA8 | c.4410C>A p.G1470= | Silent (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.333G>A p.K111= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- BLOC1S2 | c.96T>G p.P32= | Silent (SNP) | VAF 39/174 reads (22%) | catalogued as rs770112434; called by muse, mutect2, varscan2
- C12orf54 | c.303T>C p.S101= | Silent (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- DLC1 | c.3762T>C p.S1254= (on ENST00000276297 / NM_001348081.2; = p.S817= on NM_006094.5) | Silent (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- FCRL3 | c.1648C>T p.L550= | Silent (SNP) | VAF 64/290 reads (22%) | called by muse, varscan2
- H4C7 | c.273C>G p.L91= | Silent (SNP) | VAF 41/132 reads (31%) | catalogued as COSV99769318; called by muse, mutect2, varscan2
- HOXA3 | c.1017C>A p.T339= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs1216814677; called by muse, mutect2, varscan2
- IRF4 | c.804G>T p.T268= | Silent (SNP) | VAF 88/604 reads (15%) | catalogued as COSV66704996; called by muse, mutect2, varscan2
- MUC12 | c.8601A>T p.S2867= (on ENST00000379442; = p.S2724= on NM_001164462.1) | Silent (SNP) | VAF 110/4574 reads (2%) | called by muse, mutect2
- NOSIP | c.109C>A p.R37= | Silent (SNP) | VAF 103/245 reads (42%) | called by muse, mutect2, varscan2
- SLC35A5 | c.342C>T p.V114= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs930428771, COSV99656810; called by muse, mutect2, varscan2
- SUGP1 | c.1128A>T p.A376= | Silent (SNP) | VAF 63/422 reads (15%) | called by muse, mutect2
- TLN1 | c.7272C>T p.L2424= | Silent (SNP) | VAF 114/390 reads (29%) | called by muse, varscan2
- TRAV41 | c.162A>G p.L54= | Silent (SNP) | VAF 67/294 reads (23%) | called by muse, mutect2, varscan2
- VANGL1 | c.828A>C p.A276= | Silent (SNP) | VAF 125/519 reads (24%) | called by muse, mutect2, varscan2
- ANKRD42 | chr11:83193862 C>G | 5'Flank (SNP) | VAF 30/190 reads (16%) | catalogued as rs1408737814; called by muse, mutect2, varscan2
- BMERB1 | c.*741G>C | 3'UTR (SNP) | VAF 46/222 reads (21%) | called by muse, mutect2, varscan2
- CBR1 | c.398-271T>G | Intron (SNP) | VAF 65/229 reads (28%) | called by muse, mutect2, varscan2
- DPCD | c.405-3632C>G | Intron (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- OFCC1 | n.82G>T | RNA (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- RTCA | c.799+3945G>C | Intron (SNP) | VAF 32/196 reads (16%) | catalogued as COSV99559974; called by muse, mutect2, varscan2
- SSPOP | n.7942C>T | RNA (SNP) | VAF 13/109 reads (12%) | catalogued as rs560120974, COSV100947058; called by muse, mutect2, varscan2
- SSTR5-AS1 | n.1266C>A | RNA (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- TCEANC2 | c.-29C>G | 5'UTR (SNP) | VAF 36/112 reads (32%) | catalogued as COSV52371967; called by muse, mutect2, varscan2
- TNFRSF13B | c.631+37T>A | Intron (SNP) | VAF 134/545 reads (25%) | called by muse, mutect2, varscan2
- TSC22D2 | c.2030+15140G>C | Intron (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- VAPB | c.*4123C>G | 3'UTR (SNP) | VAF 24/417 reads (6%) | called by muse, mutect2
